National Lung Screening Trial (NLST) participant 104348 — screening results and lung cancer
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 59 years; Gender: male; Race: White; Cigarette smoking status at randomisation: current smoker; Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 21): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer.
- T1: No screening result: Not Expected - Cancer before screening window.
- T2: No screening result: Not Expected - Cancer before screening window.

Lung cancer (1 primary lung cancer record; the first confirmed lung cancer followed a positive screen; study year of the first confirmed lung cancer: T0; the diagnosis is linked to a positive screen through the trial's diagnostic-procedure linking algorithm)
1. First primary lung cancer, diagnosed day 42, study year T0. Site: lower lobe of lung (ICD-O-3 C34.3). Primary tumour location: right lower lobe. Histology: adenosquamous carcinoma (ICD-O-3 8560/3). Cancer type as recorded on the NLST diagnostic evaluation form (the trial's best information on type): adenocarcinoma, NOS (ICD-O-3 8140). Grade: poorly differentiated (G3). Tumour size on pathology: 40 mm. AJCC 6th edition staging: stage IIB (best stage, from pathologic TNM); clinical T2 N3 M1 (stage IV); pathologic T2 N1 M0 (stage IIB). AJCC 7th edition staging: stage IIA; clinical T2a N3 M0; pathologic T2a N1 M0.
